Somatic mutation profile of tumor specimen MMRF_1819_1_BM_CD138pos (aliquot MMRF_1819_1_BM_CD138pos_T1_KBS5U_L05384) from MMRF case MMRF_1819, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.1 years (24,865 days).
Specimen MMRF_1819_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bea4dfcd-7f2b-4435-81ef-4783aa946d51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1819_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1819_1_PB_Whole_C3_KBS5U_L05397; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de6d864d-df3c-4ad7-9af5-6fbc092a91e8

The open-access MAF lists 86 somatic variants for this specimen: 34 protein-altering or splice-affecting, 6 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 29, Intron 10, Silent 6, 5'UTR 5, Splice Region 1, Frame Shift Del 1, RNA 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 10/19 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSBG2 | c.1289C>G p.T430R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV53125271; called by muse, varscan2
- ADGRE2 | c.1885C>T p.R629W | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1359045292, COSV59692745; called by muse, mutect2
- BLOC1S4 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs1486712240; called by muse, mutect2, varscan2
- CPNE2 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs139146677; called by muse, mutect2, varscan2
- EMILIN3 | c.1627C>T p.R543W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs139770210; called by muse, mutect2, varscan2
- HECW1 | c.2558G>A p.R853H | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs891272542; called by muse, mutect2
- IGHV2-70 | c.308T>C p.M103T | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs534782395; called by mutect2, varscan2
- LATS2 | c.2554G>T p.D852Y | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV66875447; called by muse, mutect2, varscan2
- LIN7A | c.614C>A p.T205K | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.138); catalogued as COSV54022357; called by muse, mutect2
- NLRP7 | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769310230, COSV60176813; called by muse, mutect2
- OR9G1 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as rs543443299, COSV56452999; called by muse, mutect2, varscan2
- STC1 | c.163G>T p.G55W | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV51689983; called by muse, mutect2, varscan2
- TROAP | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs779395745, COSV57746302; called by muse, mutect2, varscan2
- VEGFA | c.602C>T p.T201M (on ENST00000523873 / NM_001171623.1; = p.T364M on NM_003376.6) | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776522854; called by muse, mutect2, varscan2
- BEX5 | c.179T>A p.M60K | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.383); called by muse, mutect2
- CCDC149 | c.1373G>A p.G458E (on ENST00000635206 / NM_001330643.2; = p.G447E on NM_173463.5) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- CCDC171 | c.327del p.H110Ifs*49 | Frame Shift Del (DEL) | VAF 17/40 reads (43%) | called by mutect2, pindel, varscan2
- CNGB3 | c.2309T>A p.V770D | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- COLQ | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- DCBLD2 | c.1835C>A p.T612K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0.036); called by muse, mutect2
- EPG5 | c.7558-8_7563del p.X2520_splice | Splice Site (DEL) | VAF 22/34 reads (65%) | called by mutect2, pindel, varscan2
- HDAC9 | c.1550A>C p.E517A | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- LCE4A | c.47G>A p.C16Y | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRC4C | c.610C>A p.L204I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2
- NCKAP5 | c.4430T>G p.M1477R | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NEGR1 | c.584G>T p.R195M | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- OPRK1 | c.600A>C p.K200N | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- PALB2 | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- RNF144A | c.696C>G p.C232W | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SMAP1 | c.1269+3A>G | Splice Region (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- TASOR | c.2839G>A p.A947T (on ENST00000355628 / NM_001365636.2; = p.A571T on NM_015224.3) | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.006); called by muse, mutect2
- TTC8 | c.913C>T p.P305S (on ENST00000338104 / NM_001288781.1; = p.P289S on NM_144596.4) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- TTN | c.96526G>C p.E32176Q (on ENST00000591111; = p.E24752Q on NM_003319.4) | Missense Mutation (SNP) | VAF 24/47 reads (51%) | PolyPhen benign (0.053); called by muse, mutect2, varscan2
- C1orf174 | c.711C>T p.D237= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as rs547145610, COSV59495769; called by muse, mutect2
- CHST1 | c.426G>A p.P142= | Silent (SNP) | VAF 15/21 reads (71%) | called by muse, mutect2, varscan2
- GALNT15 | c.1164G>A p.L388= | Silent (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- GTF3C1 | c.4686C>T p.D1562= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs576044105, COSV62243185; called by mutect2, varscan2
- PTPN14 | c.2031C>T p.P677= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs770086401, COSV65281347; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLCO6A1 | c.2010A>C p.V670= | Silent (SNP) | VAF 5/8 reads (63%) | called by muse, mutect2, varscan2
- ADD2 | c.-283A>G | 5'UTR (SNP) | VAF 4/12 reads (33%) | catalogued as rs1276459738; called by muse, mutect2
- AMHR2 | c.*24T>C | 3'UTR (SNP) | VAF 26/48 reads (54%) | called by muse, mutect2, varscan2
- ANGPT1 | c.*498A>G | 3'UTR (SNP) | VAF 13/27 reads (48%) | catalogued as rs901296151; called by muse, mutect2, varscan2
- ATPSCKMT | c.*238A>G | 3'UTR (SNP) | VAF 17/27 reads (63%) | called by muse, mutect2, varscan2
- BCAS1 | chr20:53940043 A>G | 3'Flank (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- BMP6 | c.*764C>G | 3'UTR (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- CAMK4 | c.*7475C>T | 3'UTR (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- CD37 | c.-41C>T | 5'UTR (SNP) | VAF 14/24 reads (58%) | called by muse, mutect2, varscan2
- CDH2 | c.*1008G>T | 3'UTR (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- DGKG | c.*2637G>C | 3'UTR (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2
- DHFR2 | c.*2986T>A | 3'UTR (SNP) | VAF 29/48 reads (60%) | called by muse, mutect2, varscan2
- ELOVL7 | c.*1630G>C | 3'UTR (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- FBXW8 | c.-62C>A | 5'UTR (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- FOXR2 | c.*54C>A | 3'UTR (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- GRIA1 | c.*670C>T | 3'UTR (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- IREB2 | c.*3050C>A | 3'UTR (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- LMO7 | c.3562+157C>T | Intron (SNP) | VAF 22/46 reads (48%) | catalogued as rs890253772; called by muse, varscan2
- LTB | c.163-50G>A | Intron (SNP) | VAF 20/38 reads (53%) | catalogued as rs1278218313; called by muse, mutect2, varscan2
- MAP1B | c.*823T>C | 3'UTR (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2, varscan2
- MIP | c.*1722A>C | 3'UTR (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- MTRF1 | c.*41G>A | 3'UTR (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2, varscan2
- MYO16 | c.*135T>A | 3'UTR (SNP) | VAF 5/49 reads (10%) | catalogued as rs928428364; called by muse, mutect2
- NAALADL2 | c.1800+5032A>C | Intron (SNP) | VAF 8/10 reads (80%) | called by muse, mutect2, varscan2
- NDP | c.*757A>T | 3'UTR (SNP) | VAF 11/11 reads (100%) | called by muse, mutect2, varscan2
- NFASC | c.1831+30C>T | Intron (SNP) | VAF 18/31 reads (58%) | catalogued as rs766070143; called by muse, mutect2, varscan2
- NPC1L1 | c.*733C>A | 3'UTR (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- PCDH7 | c.*947C>T | 3'UTR (SNP) | VAF 17/29 reads (59%) | called by muse, mutect2, varscan2
- PNPLA7 | c.3269-18G>A | Intron (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- POU2F1 | c.*1244T>C | 3'UTR (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- PPP2CB | c.-93G>C | 5'UTR (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
- PTAR1 | c.86+1346C>T | Intron (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- SAMD4A | c.*4140del | 3'UTR (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel
- SLC13A1 | c.*1750C>T | 3'UTR (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- SLC16A7 | c.218-3061G>T | Intron (SNP) | VAF 10/30 reads (33%) | called by mutect2, varscan2
- SLC7A2 | c.*2702G>T | 3'UTR (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- SPATA6 | c.*341A>C | 3'UTR (SNP) | VAF 20/39 reads (51%) | called by muse, mutect2, varscan2
- SPOPL | c.*3154G>A | 3'UTR (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- SRRM2-AS1 | n.79A>T | RNA (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- SSU72 | c.224+2297C>G | Intron (SNP) | VAF 21/38 reads (55%) | catalogued as rs922575511; called by muse, mutect2, varscan2
- ST8SIA6 | c.*894T>G | 3'UTR (SNP) | VAF 11/15 reads (73%) | called by muse, mutect2, varscan2
- TFEC | c.*2999C>T | 3'UTR (SNP) | VAF 17/28 reads (61%) | called by muse, mutect2, varscan2
- TMEM132C | c.*587_*588del | 3'UTR (DEL) | VAF 4/26 reads (15%) | catalogued as rs1366251592; called by mutect2, pindel, varscan2
- TMEM132D | c.1444-172C>T | Intron (SNP) | VAF 13/19 reads (68%) | called by muse, mutect2, varscan2
- TRIP11 | c.-351A>G | 5'UTR (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- TSLP | c.*711T>C | 3'UTR (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- UBL5 | c.57-97G>A | Intron (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
